Gene-level copy-number profile of tumor specimen TCGA-ER-A2NE-06A from TCGA case TCGA-ER-A2NE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.6 years (14,826 days).
Specimen TCGA-ER-A2NE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9d77f1e2-c1b2-493f-867e-c9bb1b0ffe1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A2NE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c28b6eb5-6644-4790-b3e4-ef49d8edef3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 18,576; copy number 2: 38,832; copy number 3: 1,936; copy number 4: 168; copy number 5: 104; copy number 6: 43; copy number 7: 57; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A2NE-06A-21D-A194-01): tumor purity 0.98, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:167,052,551–167,058,542, 1 gene: AL158837.1.
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–1): MLLT3.
- chr9:20,502,265–25,089,151, 81 genes (broad region; genes not listed).
- chr10:44,712–689,668, 13 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 207 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,719,980–65,707,226, 1 gene, copy number 5 (within-gene range 3–5): EYS.
- chr6:64,377,795–66,094,909, 7 genes, copy number 5: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:68,635,282–69,389,506, 1 gene, copy number 5 (within-gene range 1–5): ADGRB3.
- chr8:37,626,015–37,700,019, 3 genes, copy number 5 (within-gene range 1–5): AC137579.1, RNU6-607P, ZNF703.
- chr12:67,424,272–72,670,758, 103 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr17:3,802,158–5,731,085, 92 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
